Surgical pathology report (de-identified scan), TCGA case TCGA-FG-6692, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-6692-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Name:

Accession #:

Date of Procedure:

Date Received:

Submitting Physician:

Med. Rec #.

Location:

Race:

DOB/Sex:

FINAL DIAGNOSIS

A.-C. RIGHT FRONTAL LOBE OF BRAIN, LESION, BIOPSY AND REMOVAL:
-- ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III).

Note: The tumor demonstrates a brisk mitotic rate as well as focal microvascular proliferation. An addendum will be issued pending deletion analyses of chromosomes 1 and 19.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Touch imprint and microscopic: High grade glioma. -

Clinical History:

Right brain lesion

Specimens Submitted As:

A:RIGHT BRAIN LESION BX

B:RIGHT TUMOR

C:RIGHT FRONTAL LOBE

Gross Description:

A. Received fresh for intraoperative consultation, labeled with the patient's name, hospital number and "right brain tumor biopsy," are multiple, irregular, tan-pink fragments of soft tissue, 1 x 1 x 0.4 cm. A touch prep is performed on a portion of the specimen. A frozen section is performed on a portion of the specimen. The specimen is submitted entirely in two cassettes.

B:Received in formalin, labeled with the patient's name and number, is one irregular, pink-tan to red, soft tissue fragment measuring 0.9 x 0.5 x 0.2 cm. Submitted in toto in one cassette.

C: Received in formalin, labeled with the patient's name and number, are multiple irregular, pink-tan to red-brown, soft, cerebriform tissue fragments measuring in aggregate 7.6 x 6.4 x 2.6 cm. Representative sections are submitted in 4 cassettes.

Source: NCI Genomic Data Commons file 32925251-36fd-440b-a256-f01a48b181f0 (TCGA-FG-6692.83534BAB-AA85-44F8-ABE2-F4383079594E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).